Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A25I, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A25I-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS -----
THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE: Total thyroidectomy

TUMOR SITE: Left lobe

HISTOLOGIC TYPE:
Papillary carcinoma, follicular variant

TUMOR SIZE: Greatest dimension: 2.4 cm

FOCALITY: Unifocal

LYMPH NODES:
1 lymph node is negative for tumor

EXTENT OF INVASION
PRIMARY TUMOR:
pT2: Tumor >2 cm, but <4 cm, limited to thyroid

REGIONAL LYMPH NODES:
pNO: No regional lymph node metastasis

DISTANT METASTASIS:
pMX: Cannot be assessed

MARGINS: Margins are uninvolved

VENOUS/LYMPHATIC INVASION: Absent

ADDITIONAL PATHOLOGIC FINDINGS:
Marked lymphocytic thyroiditis, 2 parathyroid glands (left inferior and right).

NOTE: This case was shown at the

ICD-0-3

Carcinoma, follicular variant 83+0/3

Site: thyroid c73.9

for
5/4/11

[page 2 of 2]
GROSS DESCRIPTION

PART #1: TOTAL THYROIDECTOMY

Dictated:

The specimen is received fresh labeled with the patient's name xxxx, and is designated total thyroidectomy. The specimen is oriented with a stitch on the left thyroid nodule. The specimen measures overall 5.5 x 4.5 x 1.5 cm, and weighs 14.49 grams. Orange ink is placed on the anterior aspect of the specimen, and black ink is placed on the posterior aspect. The specimen is serially sectioned to reveal a tumor measuring 2.4 x 1.8 x 1.5 cm in the left superior pole of the thyroid. A portion of this tumor is harvested for potential future studies. The specimen is serially sectioned and no other lesions are identified. The specimen is entirely submitted.

SUMMARY OF SECTIONS:

- 1 - A - 3 DESIGNATED LEFT SUPERIOR
- 1 - B - 2 DESIGNATED LEFT SUPERIOR
- 1 - C - 3 DESIGNATED LEFT SUPERIOR
- 1 - D - 2 DESIGNATED LEFT MID AND ISTHMUS
- 1 - E - 2 DESIGNATED LEFT INFERIOR
- 1 - F - 3 DESIGNATED LEFT INFERIOR
- 1 - G - 3 DESIGNATED ISTHMUS
- 1 - H - 3 DESIGNATED RIGHT INFERIOR
- 2 - I - J 2/EACH DESIGNATED RIGHT MID
- 2 - K - L 2/EACH DESIGNATED RIGHT SUPERIOR
- 12- TOTAL - M

Source: NCI Genomic Data Commons file 2e6f5de6-264b-42a6-ab15-ef87bcc57aee (TCGA-ET-A25I.94CB3835-0E2E-4187-A3D7-52F48537520E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).